RC case RC-B5CU — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a2d27c28-4051-405d-9d2e-9d81ac41e1e9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1993; Vital status: Dead; Days to death: 243 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: Lebanon.

Diagnoses (2)
1. Peripheral T-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 23.4 years (8,561 days); Year of diagnosis: 2017; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Bone marrow / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide + Prednisone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CEP; Days to treatment start: 18 days; Days to treatment end: 189 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pralatrexate; Initial disease status: Progressive Disease; Days to treatment start: 223 days; Days to treatment end: 223 days; Reason treatment ended: Death; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 24.0 years (8,777 days); Days to diagnosis: 216 days.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 70.
- Day 216 (progression): Progression or recurrence: Yes; Days to progression: 216 days.
- Follow-up contact recording only the day: day 243.

Molecular and laboratory tests
- Lactate Dehydrogenase 2445 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hyperlipidemia / Hypertension / Anxiety / Benign Prostatic Hyperplasia.
- Timepoint category: Initial Diagnosis; Weight: 85.9 kg; Height: 165.5 cm; BMI: 31.4.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5CU-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B5CU-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide RC-B5CU-TBP1-A-1-0-CS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 100; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
